Somatic mutation profile of tumor specimen C3N-03665-01 (aliquot CPT0226760007) from CPTAC case C3N-03665, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 63.4 years (23,168 days).
Specimen C3N-03665-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55b2c800-7088-4bf7-88ed-0b33b1e99fdd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03665-31 (Blood Derived Normal), aliquot CPT0226800002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6af82fb-06dd-4615-92a2-2055488238d7

The open-access MAF lists 34 somatic variants for this specimen: 21 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 11, Splice Site 3, Nonsense Mutation 2, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 71/461 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 34/217 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs377767347, CM004254, CM100519, COSV61684056, COSV61686014, COSV61689167; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACADL | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 63/615 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as rs774103658, COSV99284538; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CILP2 | c.2890C>T p.R964C | Missense Mutation (SNP) | VAF 29/283 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as COSV52274963; called by muse, mutect2, varscan2
- DNAAF5 | c.2461C>T p.P821S | Missense Mutation (SNP) | VAF 53/448 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV99860295; called by muse, mutect2, varscan2
- TMEM132C | c.1327G>A p.A443T | Missense Mutation (SNP) | VAF 33/232 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59412833; called by muse, mutect2, varscan2
- ZNF618 | c.1768G>A p.D590N (on ENST00000374126 / NM_001318042.2; = p.D497N on NM_133374.2) | Missense Mutation (SNP) | VAF 63/490 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.284); catalogued as rs1306161813; called by muse, mutect2, varscan2
- ABCA7 | c.1857C>G p.I619M | Missense Mutation (SNP) | VAF 57/458 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ADAMTS2 | c.3355T>A p.F1119I | Missense Mutation (SNP) | VAF 39/248 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ALDH9A1 | c.457+2T>C p.X153_splice | Splice Site (SNP) | VAF 22/162 reads (14%) | called by muse, mutect2
- ARHGAP35 | c.1268T>C p.L423P | Missense Mutation (SNP) | VAF 55/456 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPD | c.238G>T p.A80S | Missense Mutation (SNP) | VAF 77/635 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- GABRA1 | c.132G>T p.R44S | Missense Mutation (SNP) | VAF 46/426 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- NOX5 | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 15/180 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- OR5L1 | c.29C>A p.A10D | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.101); called by muse, varscan2
- PARD3 | c.1684C>T p.Q562* | Nonsense Mutation (SNP) | VAF 36/352 reads (10%) | called by muse, mutect2
- PHKB | c.3003+1G>A p.X1001_splice | Splice Site (SNP) | VAF 38/426 reads (9%) | called by muse, mutect2
- PXDN | c.2793C>A p.S931R | Missense Mutation (SNP) | VAF 17/187 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.889); called by muse, mutect2
- SLITRK3 | c.643G>T p.G215* | Nonsense Mutation (SNP) | VAF 60/414 reads (14%) | called by muse, mutect2, varscan2
- USP34 | c.5434-1G>T p.X1812_splice | Splice Site (SNP) | VAF 8/73 reads (11%) | called by muse, varscan2
- ZNF544 | c.719A>C p.N240T | Missense Mutation (SNP) | VAF 34/217 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- EPHB6 | c.360C>T p.S120= | Silent (SNP) | VAF 108/1012 reads (11%) | catalogued as rs533330481, COSV67419655; called by muse, varscan2
- IZUMO3 | c.288T>C p.N96= | Silent (SNP) | VAF 24/220 reads (11%) | called by muse, mutect2, varscan2
- KSR2 | c.2007C>T p.G669= | Silent (SNP) | VAF 31/193 reads (16%) | catalogued as COSV56678389; called by muse, mutect2, varscan2
- MAP4K3 | c.1488C>T p.S496= | Silent (SNP) | VAF 27/200 reads (14%) | called by muse, mutect2, varscan2
- PCDHGA8 | c.435C>T p.I145= | Silent (SNP) | VAF 48/336 reads (14%) | catalogued as rs1242966092, COSV53921889; called by muse, mutect2, varscan2
- PXDN | c.2316G>A p.E772= | Silent (SNP) | VAF 132/880 reads (15%) | called by muse, mutect2, varscan2
- REST | c.2592A>T p.S864= | Silent (SNP) | VAF 53/354 reads (15%) | called by muse, mutect2, varscan2
- ROBO2 | c.4074C>T p.S1358= | Silent (SNP) | VAF 44/358 reads (12%) | catalogued as rs771357490; called by muse, mutect2, varscan2
- SAMD9L | c.4734A>G p.A1578= | Silent (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2
- TENM3 | c.2139C>T p.H713= | Silent (SNP) | VAF 36/382 reads (9%) | called by muse, mutect2
- TNFAIP8 | c.141T>C p.S47= | Silent (SNP) | VAF 72/543 reads (13%) | catalogued as rs755004248; called by muse, mutect2, varscan2
- DNMT1 | c.879-48G>T | Intron (SNP) | VAF 65/406 reads (16%) | catalogued as rs749914530; called by muse, mutect2, varscan2
- FBXL8 | chr16:67164515 G>A | 3'Flank (SNP) | VAF 14/124 reads (11%) | called by muse, varscan2
